Gene-level copy-number profile of tumor specimen TCGA-WD-A7RX-01A from TCGA case TCGA-WD-A7RX, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 71.2 years (26,006 days).
Specimen TCGA-WD-A7RX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.2bc50e9a-7ef6-4bc9-8821-2355cf3d52e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WD-A7RX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1390e3c-a724-43c5-b13d-72be9f4e4653

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,465; copy number 2: 41,491; copy number 3: 2,604; copy number 4: 57; copy number 5: 25; copy number 8: 135; copy number 9: 4; copy number 11: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WD-A7RX-01A-12D-A416-01): tumor purity 0.51, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 199 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:67,119,263–70,436,584, 131 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr11:70,477,277–70,604,859, 2 genes, copy number 8: AP001271.1, AP001271.2.
- chr11:75,586,918–75,669,120, 1 gene, copy number 5 (within-gene range 2–5): MAP6.
- chr11:75,635,883–77,637,794, 48 genes, copy number 5–11 (within-gene range 1–11): AP001922.2, AP001922.4, MOGAT2, RN7SL786P, AP001922.1, DGAT2, AP001922.3, AP003031.1, UVRAG-DT, UVRAG, Y_RNA, Y_RNA, PPP1R1AP1, AP003168.2, AP002340.1, WNT11, AP000785.1, LINC02761, THAP12, GVQW3, Y_RNA, AP002360.1, EMSY, AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11.
- chr11:79,402,022–81,556,425, 14 genes, copy number 5–9: MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25.
- chr11:81,842,435–81,987,813, 3 genes, copy number 5: AP002802.2, MIR4300, AP002802.1.

Autosomal genes at a single copy (total copy number 1): 15,465. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
